Gene-level copy-number profile of tumor specimen TCGA-H6-8124-01A from TCGA case TCGA-H6-8124, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 56.8 years (20,741 days).
Specimen TCGA-H6-8124-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.60835df6-f1f4-49bc-97f5-0ca1438773c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-H6-8124-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f2f1f23-28f9-4f93-b238-95a5248db6c6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 2: 13,617; copy number 3: 4,196; copy number 4: 39,628; copy number 5: 5; copy number 6: 1,869; copy number 7: 139; copy number 9: 139; copy number 11: 12; copy number 12: 61; copy number 19: 127; copy number 21: 6; copy number 36: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-H6-8124-01A-11D-2392-01): tumor purity 0.71, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:127,726,339–128,707,915, 18 genes (within-gene range 0–2): AC025160.1, AC087894.3, AC087894.2, AC087894.1, LINC02393, LINC00507, LINC00508, LINC02441, AC140121.1, LINC02369, LINC02368, AC061709.2, AC061709.1, TMEM132C, AC061709.3, MIR3612, AC023595.1, AC090424.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 346 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:86,216,785–87,909,553, 21 genes, copy number 9: SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4.
- chr7:97,851,688–97,972,985, 1 gene, copy number 19 (within-gene range 2–19): AC079781.5.
- chr7:97,885,868–102,283,958, 176 genes, copy number 12–19 (within-gene range 5–19) (broad region; genes not listed).
- chr7:102,264,706–102,426,676, 11 genes, copy number 12 (within-gene range 2–12): AC005088.1, SH2B2, MIR4285, AC091390.1, Y_RNA, PMS2P12, SPDYE6, PRKRIP1, AC091390.3, AC091390.2, MIR548O.
- chr7:118,214,669–120,006,101, 7 genes, copy number 21–36 (within-gene range 2–36): ANKRD7, AC002529.1, GTF3AP6, AC092098.1, AC079791.1, LINC02476, RNU1-29P.
- chr7:120,950,763–121,441,261, 12 genes, copy number 11: ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2.
- chr12:56,468,578–58,395,138, 95 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:67,753,701–67,978,387, 3 genes, copy number 9: AC022513.1, LINC01479, AC005294.1.
- chr12:68,001,394–68,001,548, 1 gene, copy number 9: RPL39P28.
- chr18:22,130,603–23,026,488, 19 genes, copy number 9 (within-gene range 4–9): RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
